TCGA case TCGA-61-2111 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/91a17d40-c8cb-4cce-b306-966382a8fe4a

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 61 years; Vital status: Alive.

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 61.6 years (22,517 days); Year of diagnosis: 1998; Method of diagnosis: Surgical Resection; FIGO stage: Stage IV; Tumor grade: G3; Prior treatment: No; Days to last follow up: 3,825 days (10.5 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 29 days; Days to treatment end: 133 days; Treatment dose: 3,400 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 29 days; Days to treatment end: 133 days; Treatment dose: 1,500 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Initial disease status: Recurrent Disease; Days to treatment start: 2,268 days (6.2 years); Days to treatment end: 2,373 days (6.5 years); Number of cycles: 6.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Initial disease status: Recurrent Disease; Days to treatment start: 3,079 days (8.4 years); Days to treatment end: 3,165 days (8.7 years); Number of cycles: 4; Treatment dose: 512 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide; Initial disease status: Recurrent Disease; Days to treatment start: 3,079 days (8.4 years); Days to treatment end: 3,165 days (8.7 years); Number of cycles: 4; Treatment dose: 4,000 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bevacizumab + Cyclophosphamide; Initial disease status: Recurrent Disease; Days to treatment start: 3,808 days (10.4 years).
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Medroxyprogesterone Acetate; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Megestrol Acetate; Treatment intent type: Adjuvant.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 67.7 years (24,722 days); Days to diagnosis: 2,205 days (6.0 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 2,232 days (6.1 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 2,205 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 2,205 days (6.0 years); Evidence of recurrence type: Biopsy with Histologic Confirmation.
- Days to follow up: 3,825 days (10.5 years); Disease response: With Tumor.
- Progression or recurrence: Yes; Progression or recurrence type: Distant; Evidence of progression type: Biopsy with Histologic Confirmation; Timepoint: Post Initial Treatment.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-61-2111-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.5; Intermediate dimension: 1.4; Shortest dimension: 0.3.
  Slide TCGA-61-2111-01A-01-BS1: Section location: Bottom; Percent tumor cells: 85; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 5.
  Slide TCGA-61-2111-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 75; Percent normal cells: 3; Percent necrosis: 14; Percent stromal cells: 3.
- Sample TCGA-61-2111-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 0.7; Intermediate dimension: 0.7; Shortest dimension: 0.3.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Anatomic organ subdivision: Left; Method initial path diagnosis: Tumor resection.
- Drug treatment 1: Pharmaceutical therapy drug name: Cytoxan.
- Drug treatment 2, Route of administrations: Route of administration: IV.
- Drug treatment 3: Pharmaceutical therapy drug name: Megace.
- Drug treatment 5: Pharmaceutical therapy drug name: Taxol.
- Drug treatment 9: Pharmaceutical therapy drug name: Avastin.
- Drug treatment 10: Pharmaceutical therapy drug name: Provera.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 3,825 days; disease-specific survival: no event (censored), 3,825 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 2,205 days.
